Somatic mutation profile of tumor specimen 0DWKHA from CCDI case PBCNVJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Malignant peripheral nerve sheath tumor; Tissue or organ of origin: Autonomic nervous system, NOS; Age at diagnosis: 9.5 years (3,471 days).
Specimen 0DWKHA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e465434-9183-494a-9a0d-7b335c1f16d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWKG8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b606150-db0e-492c-9700-c21528b40a63

The open-access MAF lists 23 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 5, 5'UTR 3, Nonsense Mutation 3, Intron 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.2041C>T p.R681* | Nonsense Mutation (SNP) | VAF 279/1013 reads (28%) | catalogued as rs768638173, CM000025, COSV62223641; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARHGAP45 | c.2686C>T p.R896W | Missense Mutation (SNP) | VAF 126/348 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV104398988; called by muse, mutect2, varscan2
- ASAH2 | c.1639C>T p.R547* | Nonsense Mutation (SNP) | VAF 114/1320 reads (9%) | catalogued as rs1038693698; called by muse, mutect2
- DZIP3 | c.1472C>T p.P491L | Missense Mutation (SNP) | VAF 379/1462 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as rs773750250, COSV100847575, COSV64313069; called by muse, mutect2, varscan2
- NFKBIA | c.220G>T p.G74W | Missense Mutation (SNP) | VAF 54/430 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53753635; called by muse, mutect2, varscan2
- BORA | c.220T>G p.C74G | Missense Mutation (SNP) | VAF 17/618 reads (3%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.083); called by muse, mutect2
- CEP164 | c.1730C>T p.S577F | Missense Mutation (SNP) | VAF 40/365 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DLEU7 | c.17C>A p.P6H | Missense Mutation (SNP) | VAF 89/338 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- KIF2B | c.955G>T p.G319* | Nonsense Mutation (SNP) | VAF 101/936 reads (11%) | called by muse, mutect2, varscan2
- KIF2B | c.1568G>A p.G523E | Missense Mutation (SNP) | VAF 93/897 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- KPNA5 | c.329T>A p.L110Q | Missense Mutation (SNP) | VAF 22/830 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2
- TSC22D1 | c.1503_1523del p.Q503_Q509del | In Frame Del (DEL) | VAF 100/734 reads (14%) | called by mutect2, varscan2
- UBAP1L | c.121C>T p.H41Y | Missense Mutation (SNP) | VAF 80/328 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- BMP7 | c.567G>T p.T189= | Silent (SNP) | VAF 140/964 reads (15%) | catalogued as rs547066469; called by mutect2, varscan2
- CEP164 | c.2109G>A p.L703= | Silent (SNP) | VAF 84/548 reads (15%) | called by muse, mutect2, varscan2
- CYB561 | c.258G>C p.L86= | Silent (SNP) | VAF 132/1117 reads (12%) | called by muse, mutect2, varscan2
- NRAP | c.3393C>T p.T1131= (on ENST00000359988 / NM_001322945.2; = p.T1096= on NM_006175.4) | Silent (SNP) | VAF 108/723 reads (15%) | catalogued as rs371831869; called by muse, mutect2, varscan2
- PKHD1L1 | c.9594G>A p.V3198= | Silent (SNP) | VAF 197/979 reads (20%) | catalogued as COSV101006225; called by muse, mutect2, varscan2
- CPNE8 | c.1144-58C>T | Intron (SNP) | VAF 20/326 reads (6%) | called by muse, mutect2
- FABP5 | c.-56C>A | 5'UTR (SNP) | VAF 67/237 reads (28%) | called by muse, mutect2, varscan2
- INTS2 | c.-47C>G | 5'UTR (SNP) | VAF 24/222 reads (11%) | catalogued as rs376944237; called by muse, varscan2
- MTMR8 | c.-12G>A | 5'UTR (SNP) | VAF 101/462 reads (22%) | called by muse, varscan2
- TDRD3 | c.-235+372C>T | Intron (SNP) | VAF 67/488 reads (14%) | catalogued as rs774448796; called by muse, mutect2, varscan2
